Somatic mutation profile of tumor specimen 0DWNTN from CCDI case PBCNTZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 18.1 years (6,601 days).
Specimen 0DWNTN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 382a6ffd-087f-489f-8e7e-b4a1dc7f1863.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNR1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61b3961e-d1ef-43f5-81bd-0de3ecc2cd9b

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 4, Silent 3, Frame Shift Ins 1, 3'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNA5 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 111/445 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV52904329; called by muse, mutect2, varscan2
- OGT | c.1876G>A p.D626N | Missense Mutation (SNP) | VAF 64/694 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV65483103; called by muse, mutect2
- PHF24 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 103/751 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs189099874, COSV54275646; called by muse, mutect2, varscan2
- SF3B1 | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 108/387 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.428); catalogued as rs1234164862, COSV100136080; called by muse, mutect2, varscan2
- SLC35G3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 102/509 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs749319327, COSV52010668, COSV99269229; called by muse, mutect2, varscan2
- TCF3 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs990854940; called by muse, mutect2, varscan2
- AP000721.1 | c.367C>T p.L123F | Missense Mutation (SNP) | VAF 20/84 reads (24%) | PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- EIF3A | c.74A>G p.Q25R | Missense Mutation (SNP) | VAF 68/577 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ELOA | c.1394dup p.N465Kfs*2 | Frame Shift Ins (INS) | VAF 112/602 reads (19%) | called by mutect2, varscan2
- GCH1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 69/314 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- KHDRBS2 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 94/625 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLEKHA5 | c.1848G>C p.L616= | Splice Region (SNP) | VAF 167/410 reads (41%) | called by muse, mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 37/1218 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- TTLL11 | c.803del p.F268Sfs*5 | Frame Shift Del (DEL) | VAF 131/534 reads (25%) | called by mutect2, varscan2
- CLEC18B | c.1164G>A p.E388= | Silent (SNP) | VAF 52/728 reads (7%) | catalogued as rs1172900882; called by muse, mutect2
- FZD6 | c.528G>T p.L176= | Silent (SNP) | VAF 263/1307 reads (20%) | catalogued as COSV62471570; called by muse, mutect2, varscan2
- PKP3 | c.1686G>A p.P562= | Silent (SNP) | VAF 54/250 reads (22%) | called by muse, mutect2, varscan2
- COPS3 | c.937-96A>G | Intron (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- MXD3 | chr5:177307019 G>C | 3'Flank (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- PKP2 | c.1689-24T>A | Intron (SNP) | VAF 150/584 reads (26%) | called by muse, mutect2, varscan2
- SRPK3 | c.1249-34C>T | Intron (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- ZMYM6 | c.1341+57G>C | Intron (SNP) | VAF 128/250 reads (51%) | catalogued as rs371365215; called by muse, mutect2, varscan2
